Gene-level copy-number profile of tumor specimen TCGA-ND-A4W6-01A from TCGA case TCGA-ND-A4W6, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Age at diagnosis: 68.0 years (24,835 days).
Specimen TCGA-ND-A4W6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file df317fd5-207e-48c3-8799-21e0de045ffc.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-ND-A4W6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,238 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f99092ae-60bb-4afe-93e2-f38414719a11

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 32; copy number 1: 445; copy number 2: 2,487; copy number 3: 7,846; copy number 4: 14,603; copy number 5: 19,347; copy number 6: 8,007; copy number 7: 3,169; copy number 8: 213; copy number 9: 197; copy number 10: 597; copy number 11: 1,313; copy number 12: 40; copy number 13: 41; copy number 14: 21; copy number 15: 9; copy number 16: 17; copy number 21: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ND-A4W6-01A-11D-A28Q-01): tumor purity 0.44, ploidy 4.89, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr8:12,064,389–12,177,550, 10 genes (within-gene range 0–2): DEFB130B, RNA5SP253, DEFB108D, ZNF705D, FAM66D, AC130366.1, USP17L7, USP17L2, DEFB109D, FAM90A2P.
- chr22:18,400,407–18,530,573, 8 genes: PPP1R26P3, FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B.
- chr22:18,794,414–18,794,804, 1 gene (within-gene range 0–2): AC008132.2.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 1,429 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:41,645,177–42,139,752, 13 genes, copy number 16: NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4.
- chr8:46,028,804–47,736,306, 29 genes, copy number 11 (within-gene range 9–11): AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR.
- chr8:47,736,913–84,142,463, 516 genes, copy number 11 (broad region; genes not listed).
- chr8:89,900,721–91,907,619, 26 genes, copy number 11–15: RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534, RNA5SP273, LINC01030, TMEM64, AC106038.1, AC106038.2, NECAB1, AC103770.1, C8orf88, PIP4P2, AC087439.1, AC087439.2, OTUD6B-AS1, OTUD6B, LRRC69, CPP, MIR4661, SLC26A7, AC103409.1, RN7SKP231.
- chr8:100,916,523–101,397,933, 19 genes, copy number 14: YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P.
- chr8:112,148,742–145,066,685, 506 genes, copy number 11 (broad region; genes not listed).
- chr19:29,205,320–30,909,155, 29 genes, copy number 13: UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834.
- chr19:39,498,895–40,056,231, 34 genes, copy number 11 (within-gene range 10–11): DLL3, SELENOV, EID2B, AC011500.3, TDGF1P7, EID2, AC011500.2, AC011500.1, RPS29P24, RPS29P25, RPS29P26, LGALS13, AC005176.2, AC005176.1, RPS29P30, LGALS16, LGALS17A, AC005515.1, AC093063.1, RPS29P27, LGALS14, AC006133.1, CLC, LEUTX, AC005393.1, DYRK1B, MIR6719, FBL, FCGBP, PRR13P5, PSMC4, ZNF546, AC007842.1, ZNF780B.
- chr19:55,090,914–55,881,855, 68 genes, copy number 11 (broad region; genes not listed).
- chr19:56,316,524–56,338,648, 4 genes, copy number 13 (within-gene range 10–13): Y_RNA, VN2R17P, AC006116.1, AC006116.3.
- chr19:56,368,099–57,889,074, 91 genes, copy number 11–13 (within-gene range 8–13) (broad region; genes not listed).
- chr19:58,034,025–58,362,751, 28 genes, copy number 12 (within-gene range 6–12): ZSCAN1, LETM1P2, HNRNPDLP4, ZNF135, RN7SL526P, ZSCAN18, ZNF329, AC008751.1, AC008751.3, AC008751.2, ZNF274, RPS15AP36, AC020915.3, ZNF544, AC020915.4, AC020915.2, AC020915.1, ZNF8, ZNF8-ERVK3-1, ERVK3-1, AC010642.2, AC010642.1, ZSCAN22, MIR6806, A1BG, AC012313.3, A1BG-AS1, AC012313.10.
- chr21:14,676,698–15,627,342, 17 genes, copy number 11–16: AF127936.1, POLR2CP1, GAPDHP16, AF127577.4, LINC02246, RBMX2P1, AF127577.3, NRIP1, AF127577.1, AF127577.2, AF127577.6, AF127577.5, AF246928.1, AJ009632.2, CYCSP42, AJ009632.1, RNU6-1326P.
- chr21:16,718,998–16,873,691, 3 genes, copy number 12: RNU1-98P, AF130359.1, AF212831.1.
- chr21:31,840,341–32,955,437, 30 genes, copy number 11–16 (within-gene range 9–16): TPT1P1, HUNK, HUNK-AS1, LINC00159, AP000265.1, MIS18A, MIS18A-AS1, MRAP, MRAP-AS1, URB1, SNORA80A, URB1-AS1, CFAP298-TCP10L, EVA1C, EXOSC3P1, TCP10L, AP000272.1, RNA5SP490, CFAP298, OR7E23P, AP000275.1, SYNJ1, PAXBP1-AS1, PAXBP1, C21orf62-AS1, AP000280.2, C21orf62, AP000281.1, SNORA70, AP000281.2.
- chr21:36,994,643–37,019,662, 2 genes, copy number 11: MRPL20P1, RIPPLY3.
- chr21:43,659,560–43,812,567, 7 genes, copy number 11: RRP1B, PDXK, AP001052.1, CSTB, TMEM97P1, RRP1, AATBC.
- chr21:46,598,604–46,691,226, 4 genes, copy number 15: S100B, PRMT2, DSTNP1, RPL23AP4.
- chr22:18,733,914–18,757,906, 1 gene, copy number 21: FAM230E.
- chr22:18,906,238–18,947,732, 2 genes, copy number 14 (within-gene range 5–14): AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 51. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
